Gene-level copy-number profile of tumor specimen HCM-CSHL-0658-C20-06A from HCMI case HCM-CSHL-0658-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.9 years (21,879 days).
Specimen HCM-CSHL-0658-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 19c322e7-bccd-45d5-811d-f967103ecdf6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0658-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/396d28a0-f1f3-4e4d-8605-ff5d7da3ddaf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 518; copy number 1: 686; copy number 2: 8,619; copy number 3: 18,758; copy number 4: 20,836; copy number 5: 5,208; copy number 6: 2,695; copy number 7: 1,419; copy number 8: 152; copy number 11: 2; copy number 21: 19.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:106,815,197–108,593,967, 9 genes: LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17, AC133134.1.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,648,075–2,838,823, 2 genes, copy number 11: AC246817.2, AC246817.1.
- chr8:32,911,493–32,911,598, 1 gene, copy number 21: RNU6-663P.
- chr8:38,269,704–38,382,272, 1 gene, copy number 21 (within-gene range 1–21): NSD3.
- chr8:38,335,981–38,704,855, 11 genes, copy number 21: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr17:22,090,743–22,299,893, 6 genes, copy number 21: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5.

Autosomal genes at a single copy (total copy number 1): 681. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
